MMRF case MMRF_1936 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/af227b27-8550-4ee2-b36f-243842400ae5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Dead; Days to death: 640 days (1.8 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.0 years (22,998 days); ISS stage: I; Days to last known disease status: 640 days (1.8 years); Days to last follow up: 640 days (1.8 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 57 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 97 days; Days to treatment end: 97 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Doxorubicin + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 97 days; Days to treatment end: 99 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 155 days; Days to treatment end: 242 days.
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 155 days; Days to treatment end: 256 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: Second line of therapy; Days to treatment start: 270 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: Second line of therapy; Days to treatment start: 294 days; Days to treatment end: 294 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 295 days; Days to treatment end: 295 days.
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 457 days (1.3 years); Days to treatment end: 457 days (1.3 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 457 days (1.3 years); Days to treatment end: 526 days (1.4 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 465 days (1.3 years); Days to treatment end: 529 days (1.4 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 465 days (1.3 years); Days to treatment end: 524 days (1.4 years).
   Treatment given: Therapeutic agents: Other; Regimen or line of therapy: Third line of therapy; Days to treatment start: 550 days (1.5 years); Days to treatment end: 556 days (1.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Other; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 557 days (1.5 years); Days to treatment end: 568 days (1.6 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 574 days (1.6 years); Days to treatment end: 574 days (1.6 years).
   Treatment given: Therapeutic agents: Dexamethasone + Melphalan + Other; Regimen or line of therapy: Fifth line of therapy; Days to treatment start: 578 days (1.6 years); Days to treatment end: 578 days (1.6 years).
   Treatment given: Therapeutic agents: Daratumumab + Prednisone; Regimen or line of therapy: Sixth line of therapy; Days to treatment start: 604 days (1.7 years); Days to treatment end: 625 days (1.7 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 640.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.681 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 152 mg/dL; Immunoglobulin G 4.55 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.17 g/L; Beta 2 Microglobulin 3.19 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.63 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 109 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.68 mmol/L; Albumin 41 g/L; Total Protein 6 g/dL; Glucose 5.45 mmol/L.
- Day 106 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 76.2 mg/dL; Immunoglobulin G 5.36 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 7.4 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 0.4 ×10⁹/L; Absolute Neutrophil 0.2 ×10⁹/L; Platelets 40 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.83 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.709 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 103 mg/dL; Immunoglobulin G 5.25 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 2.3 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 5.08 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 169 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.45 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 4.84 mmol/L.
- Day 277 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.836 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 17.1 mg/dL; Immunoglobulin G 5.13 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 7.13 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.11 mmol/L.
- Day 357 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.43 mg/dL; Immunoglobulin G 5.93 g/L; Immunoglobulin A 1.52 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 5.9 g/dL; Glucose 6.49 mmol/L.
- Day 465 (ECOG 0): Lactate Dehydrogenase 11.4 µkat/L; Hemoglobin 4.84 mmol/L; Leukocytes 1.5 ×10⁹/L; Absolute Neutrophil 0.6 ×10⁹/L; Platelets 7 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 4.1 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 5.83 mmol/L.
- Day 547 (ECOG 1): M Protein 0.05 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.18 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 73.8 mg/dL; Immunoglobulin G 3.19 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 5.58 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 7 ×10⁹/L; Platelets 62 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.25 mmol/L; Albumin 43 g/L; Total Protein 5.8 g/dL; Glucose 5.94 mmol/L.
- Day 637 (ECOG 2): M Protein 0.11 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 172 mg/dL; Immunoglobulin G 1.68 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.05 g/L; Lactate Dehydrogenase 13.1 µkat/L; Hemoglobin 4.03 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.6 ×10⁹/L; Platelets 13 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.25 mmol/L; Albumin 37 g/L; Total Protein 5.6 g/dL; Glucose 5.5 mmol/L.

Other clinical attributes
- Day 1: Weight: 92 kg; Height: 175 cm.

Family history
- Relative with cancer history: no.

Biospecimens (1 sample)
- Sample MMRF_1936_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
